CCDI case PBBUJZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/315e00ee-630e-4b1d-88df-23088f909d56

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 0.3 years (93 days).

Biospecimens (3 samples)
- Sample 0DH6ZY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH72L: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH731: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
